Surgical pathology report (de-identified scan), TCGA case TCGA-BR-7957, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-7957-01A (Primary Tumor).

[page 1 of 2]
TCGA Pathology Reports

Requisition [redacted] un at [redacted]

[redacted] Case ID		Gross Description	Microscopic Description	Diagnosis Details	Comments
[redacted]					

[page 2 of 2]
Formatted Path Report

STOMACH TISSUE CHECKLIST

Specimen type: Excision of tumor

Tumor site: Fundus

Tumor size: 4 x 3.5 x 1.2 cm

Tumor features: Ulcerated

Histologic type: Adenocarcinoma, intestinal type

Histologic grade: Not specified

Tumor extent: Serosa (visceral peritoneum)

Lymph nodes: 7/8 positive for metastasis

(Intraabdominal,retroperitoneal 7/8)

Lymphatic invasion: Not specified

Venous invasion: Not specified

Perineural invasion: Not specified

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

ID	Lateralit y	Excision date

Source: NCI Genomic Data Commons file 47a4d28f-dce8-4ebe-8acb-4269f264d57f (TCGA-BR-7957.90C6D25B-A9DD-4A86-86C8-8DAAC786ACC6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).